Somatic mutation profile of tumor specimen TCGA-A3-3373-01A (aliquot TCGA-A3-3373-01A-02D-1421-08) from TCGA case TCGA-A3-3373, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 54.7 years (19,964 days).
Specimen TCGA-A3-3373-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4091bd8b-49db-4475-b177-d07e19f2f932.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3373-11A (Solid Tissue Normal), aliquot TCGA-A3-3373-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6b8bda4-dec0-4e51-a315-7397061a3d9e

The open-access MAF lists 59 somatic variants for this specimen: 49 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 37, Silent 10, Frame Shift Del 5, Nonsense Mutation 3, Splice Region 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | hotspot (GDC flag); catalogued as rs119103277, CM951277, CM995326, HX971376, COSV56543204, COSV56545932, COSV56566114; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.1821-3dup | Splice Region (INS) | VAF 26/154 reads (17%) | catalogued as rs748641243; called by mutect2, varscan2
- AQP9 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54970514; called by muse, mutect2, varscan2
- ATF7IP | c.1392T>G p.N464K | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.124); catalogued as COSV53776548; called by muse, mutect2, varscan2
- ATP13A3 | c.2911A>T p.I971F | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as rs754675963, COSV55468974; called by muse, mutect2, varscan2
- CCN2 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.052); catalogued as COSV63466973; called by muse, mutect2, varscan2
- CD101 | c.2084T>C p.I695T | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs371723692; called by muse, mutect2, varscan2
- CHAF1A | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 88/378 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs61729782, COSV56671678, COSV56675931; called by muse, mutect2, varscan2
- CYP8B1 | c.185C>G p.T62S | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV60227509; called by muse, mutect2, varscan2
- DIAPH2 | c.2564G>C p.G855A | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61289421; called by muse, mutect2, varscan2
- DMD | c.189A>G p.P63= | Splice Region (SNP) | VAF 43/148 reads (29%) | catalogued as COSV55897158, COSV55898954, COSV55903919; called by muse, mutect2, varscan2
- DTD2 | c.203A>T p.K68I | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60428407; called by muse, mutect2, varscan2
- EEA1 | c.1879A>C p.N627H | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as COSV59289346; called by muse, mutect2, varscan2
- EHBP1 | c.1355G>A p.W452* | Nonsense Mutation (SNP) | VAF 62/203 reads (31%) | catalogued as COSV50434452; called by muse, mutect2, varscan2
- EIF5A | c.402+2T>C p.X134_splice | Splice Site (SNP) | VAF 62/215 reads (29%) | catalogued as COSV59752922; called by muse, mutect2, varscan2
- ELOVL2 | c.91A>C p.M31L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1237102438, COSV61156850; called by muse, mutect2, varscan2
- FNIP2 | c.370C>G p.P124A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); catalogued as COSV52444917; called by muse, mutect2, varscan2
- IGHD6-19 | c.2G>C p.G1A | Missense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as rs567783226; called by muse, mutect2, varscan2
- JOSD2 | c.201C>A p.N67K | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65350694; called by muse, mutect2, varscan2
- MAPK8IP3 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.826); catalogued as rs758271119, COSV51726280; called by muse, mutect2, varscan2
- METTL18 | c.607A>C p.I203L | Missense Mutation (SNP) | VAF 125/413 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV53682233; called by muse, mutect2, varscan2
- MFHAS1 | c.642C>G p.N214K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52286427; called by muse, mutect2, varscan2
- MMS22L | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV51525649; called by mutect2, varscan2
- NCOA3 | c.774A>T p.R258S | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV59072681; called by muse, mutect2, varscan2
- PACC1 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.99); catalogued as rs1196004170, COSV54789386; called by muse, mutect2, varscan2
- PBRM1 | c.727A>T p.K243* | Nonsense Mutation (SNP) | VAF 65/172 reads (38%) | catalogued as COSV56291840, COSV56300497; called by muse, mutect2, varscan2
- POM121C | c.1105T>C p.S369P (on ENST00000607367; = p.S127P on NM_001099415.3) | Missense Mutation (SNP) | VAF 90/334 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV57548846; called by muse, mutect2, varscan2
- R3HDML | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV53837570; called by muse, mutect2, varscan2
- RBM12 | c.592T>C p.S198P | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1268441730, COSV58294511; called by muse, mutect2, varscan2
- SH3TC1 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200988451, COSV55288997; called by muse, mutect2, varscan2
- SIRPD | c.248T>C p.F83S | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as COSV67547145; called by muse, mutect2, varscan2
- SLC15A2 | c.1298A>C p.N433T | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV55200445; called by muse, mutect2, varscan2
- SLC38A9 | c.451A>C p.M151L | Missense Mutation (SNP) | VAF 94/318 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV59425754; called by muse, mutect2, varscan2
- SLC46A3 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as COSV57184088; called by muse, mutect2, varscan2
- SRGAP1 | c.2881G>C p.D961H | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61902570; called by muse, mutect2, varscan2
- SYT7 | c.128G>C p.R43P | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55654288, COSV55658893; called by muse, mutect2, varscan2
- TARS1 | c.2127G>T p.Q709H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.637); catalogued as COSV54311989; called by muse, mutect2, varscan2
- TASOR | c.3060G>T p.L1020F (on ENST00000355628 / NM_001365636.2; = p.L644F on NM_015224.3) | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV62927907; called by muse, mutect2, varscan2
- TFDP2 | c.500A>C p.N167T (on ENST00000489671 / NM_001178139.2; = p.N106T on NM_006286.5) | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV57710722; called by muse, mutect2, varscan2
- TLR4 | c.1999T>A p.Y667N (on ENST00000355622 / NM_138554.5; = p.Y627N on NM_003266.4) | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.791); catalogued as COSV62922403, COSV62924126; called by muse, mutect2, varscan2
- TNKS2 | c.3448del p.E1150Sfs*3 | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | catalogued as COSV100861155; called by mutect2, pindel, varscan2
- UGT2B11 | c.1571A>C p.K524T | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV71424251; called by muse, mutect2, varscan2
- UTRN | c.3770A>G p.K1257R | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs375665025; called by muse, mutect2, varscan2
- VAV2 | c.1949G>A p.C650Y (on ENST00000371850 / NM_001134398.2; = p.C640Y on NM_003371.4) | Missense Mutation (SNP) | VAF 63/211 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV64084774; called by muse, mutect2, varscan2
- AFAP1L2 | c.609del p.L204Cfs*15 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- KRT25 | c.411_426del p.D138Rfs*40 | Frame Shift Del (DEL) | VAF 40/234 reads (17%) | called by mutect2, pindel
- NOL10 | c.401del p.P134Qfs*28 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- PICALM | c.234_242del p.L79_T81del | In Frame Del (DEL) | VAF 24/106 reads (23%) | called by mutect2, pindel, varscan2
- TMEM222 | c.384del p.S129Lfs*24 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- DAAM1 | c.3174A>G p.K1058= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV62839264; called by muse, mutect2, varscan2
- MAP2 | c.4110C>T p.D1370= | Silent (SNP) | VAF 39/182 reads (21%) | catalogued as rs147926728; called by muse, mutect2, varscan2
- MBD5 | c.2340T>G p.L780= | Silent (SNP) | VAF 79/294 reads (27%) | catalogued as COSV68698757; called by muse, mutect2, varscan2
- OR4F17 | c.643C>T p.L215= | Silent (SNP) | VAF 14/139 reads (10%) | called by mutect2, varscan2
- PRPF31 | c.361A>C p.R121= | Silent (SNP) | VAF 113/417 reads (27%) | catalogued as COSV58085604, COSV58086800; called by muse, mutect2, varscan2
- SCAF11 | c.489A>G p.G163= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as COSV65478785; called by muse, mutect2, varscan2
- SCN1A | c.2139A>G p.A713= (on ENST00000303395 / NM_001202435.3; = p.A702= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/238 reads (19%) | catalogued as rs1479333910, COSV57684596; called by muse, mutect2, varscan2
- SLC25A20 | c.486G>A p.E162= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV59804572; called by muse, mutect2, varscan2
- TRIM32 | c.960T>C p.V320= | Silent (SNP) | VAF 26/105 reads (25%) | catalogued as COSV57812721; called by muse, mutect2, varscan2
- TUFM | c.162C>T p.Y54= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs755627049, CD161313, COSV57949721; called by muse, mutect2, varscan2
